Somatic mutation profile of tumor specimen TCGA-ZB-A96G-01A (aliquot TCGA-ZB-A96G-01A-11D-A428-09) from TCGA case TCGA-ZB-A96G, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 59.1 years (21,598 days).
Specimen TCGA-ZB-A96G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9293af6d-1c6f-41f8-85ad-41c37efc69c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZB-A96G-10A (Blood Derived Normal), aliquot TCGA-ZB-A96G-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39673c0e-4a69-4464-951f-7af803143a01

The open-access MAF lists 9 somatic variants for this specimen: 9 protein-altering or splice-affecting.
By variant classification: Missense Mutation 7, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 18/522 reads (3%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2
- RPAP1 | c.2604del p.S869Afs*119 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | catalogued as rs778992044; called by mutect2, pindel, varscan2
- TMEM59L | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.207); catalogued as COSV53241684, COSV99450259, COSV99450460; called by muse, mutect2
- TSPEAR | c.1235A>G p.K412R | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0.009); catalogued as COSV104404023; called by muse, mutect2
- ARID4A | c.1291G>T p.A431S | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- DAAM1 | c.2191-1G>T p.X731_splice | Splice Site (SNP) | VAF 4/46 reads (9%) | called by muse, varscan2
- RC3H2 | c.2072A>G p.Y691C | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- TAF1L | c.1621T>A p.S541T | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.011); called by muse, mutect2
- TNKS1BP1 | c.3403G>A p.A1135T | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2
